CCDI case PBBUTB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/367b7821-96db-48b7-9507-63941c8078c8

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,830 days).

Biospecimens (3 samples)
- Sample 0DI7SB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI7VA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DI7VF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
